Somatic mutation profile of tumor specimen 0DL6RY from CCDI case PBBYPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.8 years (303 days).
Specimen 0DL6RY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cebfbb1-29fa-4aa9-bbba-6f05a4e54860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fda328f-42ec-435f-ae09-dd213de45883

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs755540036, COSV52266184; called by muse, mutect2
- ITGB4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs756649625, COSV52327733; called by muse, mutect2, varscan2
- SACS | c.11803C>T p.Q3935* | Nonsense Mutation (SNP) | VAF 25/187 reads (13%) | catalogued as rs1285859028, CM163058; called by muse, mutect2, varscan2
- GRIA3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 66/428 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- BFAR | c.69C>T p.T23= | Silent (SNP) | VAF 125/336 reads (37%) | catalogued as rs180778462; called by muse, varscan2
